TCGA case TCGA-VF-A8AA — Testicular Germ Cell Tumors (TCGA-TGCT)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Germ Cell Neoplasms; Primary site: Testis; Tissue source site: University of Pennsylvania. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b0df5500-d608-416e-82f4-9a99206d24c8

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 51 years; Year of birth: 1959; Vital status: Alive.

Diagnoses (2)
1. Seminoma, NOS (the primary disease): ICD-O-3 morphology code: 9061/3; ICD-10 code: C62.9; Tissue or organ of origin: Testis, NOS; Site of resection or biopsy: Testis, NOS; Laterality: Right; Classification of tumor: primary; Age at diagnosis: 51.9 years (18,940 days); Year of diagnosis: 2011; Method of diagnosis: Orchiectomy; AJCC staging edition: 7th; AJCC clinical T: T1; AJCC clinical N: N0; AJCC clinical M: M0; AJCC clinical stage: Stage I; AJCC pathologic T: T1; AJCC pathologic N: N0; AJCC pathologic M: M0; AJCC pathologic stage: Stage I; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 1,146 days (3.1 years); Ajcc serum tumor markers: SX; Sites of involvement: Rete Testis / Tunica Albuginea.
   Pathology details: Lymph node dissection site: Retroperitoneal; Lymph nodes removed: Yes; Timepoint category: Post Adjuvant Therapy.
   Pathology details: Intratubular germ cell neoplasia present: No; Lymphatic invasion present: No; Vascular invasion present: No.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 1,077 days (2.9 years); Days to treatment end: 1,109 days (3.0 years); Treatment outcome: Complete Response; Treatment anatomic sites: Locoregional Site.
   Treatment given: Treatment type: Surgery, NOS; Treatment anatomic sites: Testis.
   Recorded as not given: adjuvant Pharmaceutical Therapy, NOS.
2. Recurrence of diagnosis 1 (Seminoma, NOS), site: Lymph node, NOS. Age at diagnosis: 54.8 years (19,999 days); Days to diagnosis: 1,059 days (2.9 years); Prior treatment: Yes.

Follow-up (4 entries)
- Days to follow up: 871 days (2.4 years); Disease response: Tumor Free.
- Day 1,059 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Progression or recurrence anatomic site: Lymph node, NOS; Days to recurrence: 1,059 days (2.9 years).
- Days to follow up: 1,146 days (3.1 years); Disease response: Tumor Free.
- Follow-up contact recording only the day: follow-up.

Molecular and laboratory tests (laboratory values one line per visit day)
- Day 87: Alpha Fetoprotein 1; Testosterone 298.

Other clinical attributes
- Timepoint category: Prior to Diagnosis; Fertility history: Conceived 1 or more children by unspecified method; Risk factors: Undescended Testis; Undescended testis corrected: Yes; Undescended testis corrected age range: 3-9 years; Undescended testis history: Yes; Undescended testis history laterality: Right.

Family history
- Relative with cancer history: yes; Relationship type: Other; Relationship primary diagnosis: Kidney Cancer.
- Relative with cancer history: yes; Relationship type: Nephew; Relationship primary diagnosis: Testicular Cancer.
- Relative with cancer history: yes; Relationship type: Other; Relationship primary diagnosis: Colorectal Cancer.
- Relative with cancer history: yes; Relationship type: Natural Mother; Relationship primary diagnosis: Breast Cancer.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-VF-A8AA-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 150 mg.
  Slide TCGA-VF-A8AA-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-VF-A8AA-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-VF-A8AA-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; History of undescended testis: Yes, right testicle only; History hypospadias: No; History fertility: Fathered > or = 1 child by unspecified method; Tumor status: Tumor free.
- Primary pathology: Submitted tumor site: Testes; Testis tumor macroextent: Involves extratesticular structures: Tunica albuginea; Testis tumor microextent: Rete Testis; Intratubular germ cell neoplasm: Absent; Lymphovascular invasion: No; Post orchi lymph node dissection: No; First treatment success: No Measureable Tumor or Tumor Markers.
- Primary pathology, Histology list, Histology: Histologic diagnosis: Seminoma, NOS.
- Primary pathology, Post orchi serum marker info: Post orchi afp: 1; Post orchi testosterone: 298.
- Primary pathology, Molecular test result list: Molecular test result: Lactate Dehydrogenase (LDH) - Normal; Molecular test result: Human Chorionic Gonadotropin (HCG) - Normal; Molecular test result: Alpha Fetaprotein (AFP) - Normal.
- Follow-up form: Lost to follow-up: No; Post orchi lymph node dissection: Yes - After chemotherapy; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 1,146 days; disease-specific survival: no event (censored), 1,146 days; disease-free interval: event (new tumor event after initially disease-free), 1,059 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 1,059 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-VF-A8AA-01A-11D-A434-01): tumor purity 0.32, ploidy 3.55, whole-genome doublings 1.
